Somatic mutation profile of tumor specimen C3N-00312-04 (aliquot CPT0009070009) from CPTAC case C3N-00312, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 68.8 years (25,123 days).
Specimen C3N-00312-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bf926cb-4ed1-4b58-9837-c7d0ca263701.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00312-31 (Blood Derived Normal), aliquot CPT0009090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9313900-1c44-46e1-b037-1bde4743c3b7

The open-access MAF lists 95 somatic variants for this specimen: 68 protein-altering or splice-affecting, 16 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Frame Shift Del 7, Splice Site 4, 3'UTR 4, Splice Region 3, Nonsense Mutation 3, In Frame Del 2, Intron 2, RNA 2, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CATSPERG | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.723); catalogued as rs1366216301; called by muse, mutect2, varscan2
- CHD7 | c.6499G>A p.V2167I | Missense Mutation (SNP) | VAF 116/223 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs971937875; called by muse, mutect2, varscan2
- DSC1 | c.2407G>A p.V803I | Missense Mutation (SNP) | VAF 33/517 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1218671127, COSV57145820; called by muse, mutect2
- GGA3 | c.1445C>T p.S482F (on ENST00000537686 / NM_138619.4; = p.S449F on NM_014001.5) | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1178473582; called by muse, mutect2, varscan2
- HPS6 | c.629C>G p.P210R | Missense Mutation (SNP) | VAF 193/680 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs753587696; called by muse, mutect2, varscan2
- IFT81 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767705291; called by muse, mutect2, varscan2
- LPAR6 | c.756T>G p.Y252* | Nonsense Mutation (SNP) | VAF 100/280 reads (36%) | catalogued as rs944321155, CM153496; called by muse, mutect2, varscan2
- MAPT | c.1677C>G p.N559K (on ENST00000262410 / NM_001377265.1; = p.N167K on NM_005910.5) | Missense Mutation (SNP) | VAF 127/460 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52242881; called by muse, mutect2, varscan2
- NIPBL | c.7955C>A p.S2652* | Nonsense Mutation (SNP) | VAF 15/409 reads (4%) | catalogued as COSV56949244; called by muse, mutect2
- PCLO | c.2974A>G p.K992E | Missense Mutation (SNP) | VAF 97/325 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); catalogued as rs1246670068; called by muse, mutect2, varscan2
- PHTF1 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 145/427 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs759006715; called by muse, mutect2, varscan2
- PPP1R12C | c.2008C>G p.P670A | Missense Mutation (SNP) | VAF 87/302 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52383486; called by muse, mutect2, varscan2
- RYR1 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 190/658 reads (29%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.987); catalogued as COSV62108397; called by muse, mutect2, varscan2
- SH3PXD2A | c.1555C>T p.R519W (on ENST00000369774 / NM_001365079.1; = p.R491W on NM_014631.2) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100280177, COSV60118315; called by muse, mutect2, varscan2
- TCOF1 | c.2659-1G>C p.X887_splice (on ENST00000377797 / NM_001135243.1; = p.X810_splice on NM_000356.4) | Splice Site (SNP) | VAF 173/571 reads (30%) | catalogued as COSV60345624; called by muse, mutect2, varscan2
- YLPM1 | c.4604C>A p.S1535* | Nonsense Mutation (SNP) | VAF 149/301 reads (50%) | catalogued as COSV53119977; called by muse, mutect2, varscan2
- ZNF655 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs774474239, COSV53159970; called by muse, mutect2, varscan2
- ZNF790 | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63213016; called by muse, mutect2, varscan2
- ADCY9 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 163/544 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ASIC2 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 142/457 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ATP11B | c.2095G>C p.G699R | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCAN | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BSN | c.5665C>A p.L1889I | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CENPV | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CFAP74 | c.4664_4666del p.P1555del | In Frame Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.3749G>A p.G1250D | Missense Mutation (SNP) | VAF 67/523 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL6A6 | c.4783G>C p.E1595Q | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- CRYBG1 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 100/268 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAI4 | c.1291+2T>A p.X431_splice | Splice Site (SNP) | VAF 93/261 reads (36%) | called by muse, mutect2, varscan2
- DNAJC1 | c.635+2T>C p.X212_splice | Splice Site (SNP) | VAF 64/185 reads (35%) | called by muse, mutect2, varscan2
- DNM2 | c.2443C>A p.P815T (on ENST00000355667 / NM_001005360.3; = p.P811T on NM_004945.3) | Missense Mutation (SNP) | VAF 116/332 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EYA3 | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAL | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 131/443 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- GCN1 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRN | c.934-2A>G p.X312_splice | Splice Site (SNP) | VAF 164/500 reads (33%) | called by muse, mutect2, varscan2
- HCN4 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HMCN1 | c.9224C>A p.T3075N | Missense Mutation (SNP) | VAF 164/612 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- HSPA8 | c.1677A>T p.Q559H | Missense Mutation (SNP) | VAF 113/347 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- IGKV1-12 | c.257del p.G86Afs*? | Frame Shift Del (DEL) | VAF 111/753 reads (15%) | called by mutect2, pindel, varscan2
- ITPRID2 | c.332del p.S111Ifs*44 | Frame Shift Del (DEL) | VAF 67/278 reads (24%) | called by mutect2, pindel, varscan2
- KCNC2 | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- LHX6 | c.253-4C>A | Splice Region (SNP) | VAF 62/177 reads (35%) | called by muse, mutect2, varscan2
- LILRB2 | c.1615A>G p.T539A | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- LRP2 | c.2873T>G p.L958R | Missense Mutation (SNP) | VAF 93/317 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- MTRF1L | c.188A>C p.E63A | Missense Mutation (SNP) | VAF 197/732 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MYO7A | c.2272T>G p.F758V | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NBPF14 | c.7948C>G p.L2650V | Missense Mutation (SNP) | VAF 165/558 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NLGN2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 197/578 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR2C1 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 99/325 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OBSCN | c.9382T>C p.W3128R | Missense Mutation (SNP) | VAF 141/423 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2L3 | c.826T>G p.F276V | Missense Mutation (SNP) | VAF 88/348 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- OR4Q2 | c.166A>G p.N56D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- PBRM1 | c.3755del p.N1252Mfs*17 (on ENST00000296302 / NM_001366071.2; = p.N1227Mfs*17 on NM_018313.5) | Frame Shift Del (DEL) | VAF 103/240 reads (43%) | called by mutect2, pindel, varscan2
- PPP2CA | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC16A12 | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 128/509 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SORBS2 | c.286G>A p.D96N (on ENST00000284776 / NM_021069.5; = p.D142N on NM_003603.6) | Missense Mutation (SNP) | VAF 107/312 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAT6 | c.1097A>G p.K366R | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SYNE2 | c.13226_13270del p.M4409_S4424delinsT | In Frame Del (DEL) | VAF 34/206 reads (17%) | called by mutect2, pindel
- TMEM108 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TRGV8 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTLL7 | c.1861_1862delinsA p.F621Ifs*6 | Frame Shift Del (DEL) | VAF 62/413 reads (15%) | called by pindel, varscan2*
- UBE2D3 | c.27A>G p.E9= | Splice Region (SNP) | VAF 95/330 reads (29%) | called by muse, mutect2, varscan2
- UNC13B | c.1215G>A p.G405= | Splice Region (SNP) | VAF 60/149 reads (40%) | called by muse, mutect2, varscan2
- USH2A | c.15174del p.L5059Cfs*3 | Frame Shift Del (DEL) | VAF 84/322 reads (26%) | called by mutect2, pindel, varscan2
- VHL | c.402dup p.L135Ifs*9 | Frame Shift Ins (INS) | VAF 118/303 reads (39%) | called by mutect2, pindel, varscan2
- WDR54 | c.1003_1004del p.*335Rfs*? | Frame Shift Del (DEL) | VAF 64/269 reads (24%) | called by pindel, varscan2
- ZNF19 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 120/408 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ZNF649 | c.1119del p.F374Lfs*88 | Frame Shift Del (DEL) | VAF 58/224 reads (26%) | called by mutect2, pindel, varscan2
- ADH4 | c.537A>C p.G179= | Silent (SNP) | VAF 72/241 reads (30%) | called by muse, mutect2, varscan2
- AUTS2 | c.102G>T p.A34= | Silent (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- BRD3 | c.1161C>T p.C387= | Silent (SNP) | VAF 60/204 reads (29%) | catalogued as rs1185563179, COSV100325348; called by muse, mutect2, varscan2
- CALB2 | c.516C>T p.G172= | Silent (SNP) | VAF 61/284 reads (21%) | called by muse, mutect2, varscan2
- CARD11 | c.2961G>A p.T987= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as rs368214396, COSV101210630; called by muse, mutect2
- CDK13 | c.1035A>T p.G345= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- CSMD2 | c.6570C>T p.N2190= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs377152497; called by muse, mutect2, varscan2
- DDX17 | c.1581A>G p.L527= | Silent (SNP) | VAF 224/768 reads (29%) | catalogued as rs369638680; called by muse, mutect2, varscan2
- DST | c.10587A>G p.V3529= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1292771928; called by muse, mutect2, varscan2
- EXOSC9 | c.468C>G p.A156= | Silent (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- FBLN7 | c.930C>T p.Y310= | Silent (SNP) | VAF 67/183 reads (37%) | catalogued as rs148395500; called by muse, mutect2, varscan2
- ITGA7 | c.3165G>A p.L1055= (on ENST00000555728; = p.L1011= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 218/752 reads (29%) | catalogued as COSV57696802; called by muse, mutect2, varscan2
- PDE8B | c.792A>G p.K264= | Silent (SNP) | VAF 103/370 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.24864T>C p.A8288= (on ENST00000591111; = p.A7361= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/223 reads (31%) | called by muse, mutect2, varscan2
- TUBB6 | c.270C>T p.F90= | Silent (SNP) | VAF 122/430 reads (28%) | catalogued as rs1324251587, COSV100480964; called by muse, varscan2
- ZFP36 | c.348G>T p.R116= (on ENST00000594442; = p.R110= on NM_003407.5) | Silent (SNP) | VAF 84/265 reads (32%) | called by muse, mutect2, varscan2
- BRCA1 | c.*790G>T | 3'UTR (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- BTBD10 | c.101+5043A>C | Intron (SNP) | VAF 55/155 reads (35%) | catalogued as rs1194565378; called by muse, mutect2, varscan2
- COG6 | c.-61G>A | 5'UTR (SNP) | VAF 148/495 reads (30%) | catalogued as rs770910922; called by muse, mutect2, varscan2
- DNPH1 | c.196+192T>C | Intron (SNP) | VAF 26/162 reads (16%) | called by muse, mutect2, varscan2
- MFSD4B | c.*415T>A | 3'UTR (SNP) | VAF 91/251 reads (36%) | called by muse, mutect2, varscan2
- PAK1 | c.*115T>A | 3'UTR (SNP) | VAF 74/253 reads (29%) | called by muse, mutect2, varscan2
- POM121L9P | n.773C>T | RNA (SNP) | VAF 122/646 reads (19%) | catalogued as rs1209058384; called by muse, mutect2, varscan2
- RAB37 | chr17:74737083 C>A | 5'Flank (SNP) | VAF 18/252 reads (7%) | called by muse, mutect2
- SEC31B | c.*11del | 3'UTR (DEL) | VAF 64/210 reads (30%) | called by mutect2, pindel, varscan2
- UBE2Q2L | n.230C>G | RNA (SNP) | VAF 20/94 reads (21%) | called by mutect2, varscan2
- XIAP | chrX:123860160 C>T | 5'Flank (SNP) | VAF 179/280 reads (64%) | called by muse, mutect2, varscan2
